Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A75K, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A75K-01A (Primary Tumor).

Final Diagnosis:

A-B. Brain, right frontal mass #1 and #2, biopsies: Anaplastic oligoastrocytoma (WHO grade III).

Immunohistochemical stains were performed on paraffin sections (block A1) using antibodies directed against the following antigens: IDH1-R132H, p53 protein, and Ki-67.

p53 protein: Variably expressed in a moderate number of tumor cells.

Mutant IDH1 (IDH1-R132H): Positive in tumor cells consistent with IDH1 mutation.

Ki-67: Labeling index is at least moderate (up to 10-12%).

The findings support the above diagnosis.

Interpreted by:

Report electronically signed by

ADDENDA:

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the
For interpretation, see Synthesis in Labs under Genetics

Transcribed by

Signed by

continued next page Page 1 of 2

ICD-O-3
Oligoastrocytoma, grade III
938213
Site: Brain, supratentorial NOS
C71.0
W 8/12/13

Source: NCI Genomic Data Commons file 834a7fe4-0094-4356-9bd7-c571d093a103 (TCGA-DB-A75K.9ED9A0B1-8854-4E44-BD86-986EE3B6D7A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).